CCDI case PBBZYH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/3639bfdd-f3ff-4ae9-8e9f-ebfddfe12a6a

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, NOS: ICD-O-3 morphology code: 9040/3; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 17.0 years (6,207 days).

Biospecimens (3 samples)
- Sample 0DPBF9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPBFR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPBGS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
